CPTAC case C3L-03372 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a9f3c3c8-d353-42b6-9efb-cfcd2f2c4dc1

Demographics
Sex at birth: male; Race: white; Year of birth: 1987; Vital status: Alive; Country of birth: Russia.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Frontal lobe; Age at diagnosis: 31.6 years (11,529 days); Year of diagnosis: 2018; Days to last known disease status: 359 days; Days to last follow up: 359 days.
   Pathology details: Greatest tumor dimension: 8 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 359 days; Disease response: With Tumor; Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 359 days; Disease response: Progressive Disease.

Other clinical attributes
- Weight: 79 kg; Height: 182 cm; BMI: 23.85.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03372-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 466 mg; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03372-24: Section location: Frontal Lobe; Percent tumor nuclei: 70; Percent necrosis: 10.
- Sample C3L-03372-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -6 days; Method of sample procurement: Blood Draw.
